Somatic mutation profile of tumor specimen TARGET-10-PARHFF-09A (aliquot TARGET-10-PARHFF-09A-01D) from TARGET case TARGET-10-PARHFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.2 years (3,711 days).
Specimen TARGET-10-PARHFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab1c3cd0-7c63-4479-a565-23d82d548a44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHFF-10A (Blood Derived Normal), aliquot TARGET-10-PARHFF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe445ff1-8da5-420d-9c57-954aacc368e4

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Intron 6, Silent 4, Nonsense Mutation 3, 3'UTR 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PTPN11 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOA1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as rs373545875; called by muse, mutect2, varscan2
- BACE2 | c.1173T>A p.Y391* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV57739640; called by muse, mutect2, varscan2
- CDR1 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100983434; called by muse, mutect2, varscan2
- COL2A1 | c.3925G>T p.D1309Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61534457; called by muse, mutect2, varscan2
- CUBN | c.9349C>T p.R3117C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs375906166, COSV64729645; called by muse, mutect2, varscan2
- DMBT1 | c.6890C>T p.P2297L (on ENST00000338354 / NM_001377530.1; = p.P1540L on NM_004406.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs371601589, COSV57536503; called by muse, mutect2, varscan2
- DOP1A | c.6094G>A p.V2032I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); catalogued as rs773339340; called by muse, mutect2, varscan2
- ECI2 | c.553A>G p.I185V (on ENST00000380118 / NM_206836.3; = p.I155V on NM_006117.2) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746632168, COSV60988174; called by muse, mutect2, varscan2
- FAM47A | c.2207C>A p.P736Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60498310; called by muse, mutect2, varscan2
- FCGBP | c.12391C>T p.R4131C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs542126929; called by muse, mutect2, varscan2
- FSIP2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs1382460162; called by muse, mutect2, varscan2
- GLI2 | c.3842G>A p.R1281H (on ENST00000361492 / NM_001374353.1; = p.R1298H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs370407550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GREB1L | c.4039G>A p.V1347M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52559078; called by muse, mutect2
- NR4A1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs753307408; called by muse, mutect2, varscan2
- NRG3 | c.2008C>T p.R670W (on ENST00000404547 / NM_001370084.1; = p.R646W on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs560914369, COSV64584547; called by muse, mutect2, varscan2
- RSAD1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1169756916; called by muse, mutect2, varscan2
- SOGA3 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64107087; called by muse, mutect2, varscan2
- SSTR5 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs761743016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT6 | c.929G>A p.R310H (on ENST00000610222 / NM_001366225.1; = p.R225H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776030947, COSV65772550; called by muse, mutect2, varscan2
- TFDP1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs140523394; called by mutect2, varscan2
- TTC29 | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100283311; called by muse, mutect2, varscan2
- UBAP2 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs773874631; called by muse, mutect2, varscan2
- DLGAP5 | c.601_602insACTCCCC p.T201Nfs*36 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- DNAH9 | c.11972G>C p.S3991T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- GABRG2 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GREB1 | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GRID2 | c.2675A>G p.H892R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MET | c.3745T>G p.W1249G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCH2 | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- PGR | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PIK3CG | c.2524A>T p.M842L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SNRNP70 | c.265+2dup p.X89_splice | Splice Site (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- TNFSF9 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRPM3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBN2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.6486T>C p.N2162= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- ERCC6L | c.378A>G p.L126= | Silent (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- OTUD7A | c.315G>A p.Q105= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1248251901; called by muse, mutect2, varscan2
- SLC38A10 | c.525C>T p.H175= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs146728538, COSV55843207; called by muse, varscan2
- AC243725.1 | n.366T>G | RNA (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- COL9A1 | c.976-9C>T | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- KLK11 | c.294-36C>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PEX5 | c.148-18T>G | Intron (SNP) | VAF 25/49 reads (51%) | catalogued as rs1208254383; called by muse, mutect2, varscan2
- SLC30A9 | c.*128G>A | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- SLC6A5 | c.*60G>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SYP | c.102+21T>A | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- SYT10 | c.-103C>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- TPD52L1 | c.136-34C>G | Intron (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- WEE2 | c.1392+15G>A | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
